Gene-level copy-number profile of tumor specimen TCGA-NC-A5HK-01A from TCGA case TCGA-NC-A5HK, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 58.9 years (21,531 days).
Specimen TCGA-NC-A5HK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.dbe1132c-b10a-4928-8169-13304667f8c7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-NC-A5HK-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/576d3537-bf7a-4479-872c-411365bd7701

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 57; copy number 1: 357; copy number 2: 24,321; copy number 3: 17,615; copy number 4: 7,124; copy number 5: 4,616; copy number 6: 4,472; copy number 7: 230; copy number 8: 374; copy number 9: 215; copy number 10: 249; copy number 11: 31; copy number 13: 20; copy number 19: 134.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-NC-A5HK-01A-11D-A26L-01): tumor purity 0.48, ploidy 3.05, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 57 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,967,752–27,610,745, 57 genes (within-gene range 0–4): CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1, IZUMO3, AL353811.1, RMRPP5, RN7SKP120, AL353730.1, TUSC1, LINC01241, FAM71BP1, AL353753.1, AL442639.1, AL451137.2, AL451137.1, AL356133.1, CAAP1, H3P31, RN7SL100P, PLAA, IFT74, IFT74-AS1, LRRC19, AL355432.1, TEK, RNA5SP280, AL355433.1, LINC00032, EQTN, MOB3B, AL163192.1, AL451123.2, IFNK, AL451123.1, C9orf72, CTAGE12P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 10,068 genes in 33 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:55,868,254–72,282,539, 238 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr1:208,022,242–248,919,946, 880 genes, copy number 5–9 (within-gene range 3–9) (broad region; genes not listed).
- chr2:38,814–82,819,264, 1,383 genes, copy number 6 (broad region; genes not listed).
- chr2:95,165,432–114,007,304, 461 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr2:149,038,107–149,215,262, 1 gene, copy number 5 (within-gene range 4–5): LYPD6B.
- chr2:149,170,561–199,071,791, 670 genes, copy number 5 (broad region; genes not listed).
- chr3:11,745–22,373,321, 315 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr3:24,117,153–28,538,122, 50 genes, copy number 5–13 (within-gene range 4–13): THRB, RPL31P20, THRB-IT1, THRB-AS1, AC012087.2, AC012087.1, EIF3KP2, AC092422.1, RN7SL216P, RNA5SP125, RARB, CFL1P7, RNA5SP126, H3P10, AC093416.1, TOP2B, AC093416.2, MIR4442, CRIP1P2, NGLY1, AC092798.1, TAF9BP1, OXSM, LINC00692, RPEP2, HMGB3P12, VENTXP4, AC099754.1, LRRC3B, NEK10, MICOS10P3, RNU6-342P, AC099535.2, SLC4A7, RPS20P15, AC099535.1, RNU1-96P, AC137675.1, Y_RNA, AC098614.1, AC098614.2, KIAA1143P2, LINC02084, EOMES, LINC01980, LINC01981, LINC01967, CMC1, AZI2, ZCWPW2.
- chr3:28,427,963–28,448,073, 2 genes, copy number 8: FAM96AP1, AC093142.1.
- chr3:31,161,704–38,542,161, 122 genes, copy number 9 (within-gene range 2–9) (broad region; genes not listed).
- chr3:87,051,192–91,513,775, 33 genes, copy number 8–13: PPATP1, LINC00506, MIR4795, CHMP2B, POU1F1, KRT8P25, APOOP2, PSMC1P6, AC108749.1, RNU6-873P, HTR1F, RNU6ATAC6P, CGGBP1, AC119733.1, ZNF654, CBX5P1, C3orf38, ABCF2P1, CSNKA2IP, Y_RNA, NDUFA5P5, ICE2P2, GAPDHP50, EPHA3, AC109129.1, MTCO2P6, MTCO1P6, U3, RNU6-712P, PROS2P, HSPE1P19, ABBA01000933.1, ABBA01000935.2.
- chr3:139,316,157–175,810,548, 532 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr3:175,609,479–198,222,513, 491 genes, copy number 6 (broad region; genes not listed).
- chr5:58,198–44,828,592, 704 genes, copy number 7–10 (broad region; genes not listed).
- chr6:905,445–42,217,861, 1,212 genes, copy number 5–6 (broad region; genes not listed).
- chr6:42,879,616–63,193,630, 305 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr7:63,011,463–63,368,156, 21 genes, copy number 6: RNU6-417P, AC069285.2, AC069285.3, ZNF90P3, SAPCD2P4, SEPTIN14P1, AC069285.1, AC092001.1, PHKG1P1, AC006455.8, SEPTIN7P4, AC006455.7, ZNF733P, AC006455.1, ARAFP3, AC006455.6, AC006455.5, AC006455.2, AC006455.3, AC006455.4, VN1R31P.
- chr7:128,207,872–129,213,545, 59 genes, copy number 6 (within-gene range 3–6): MIR129-1, LEP, AC018635.2, RBM28, AC018635.1, RNU7-27P, PRRT4, IMPDH1, AC010655.1, RNU7-54P, AC010655.4, HILPDA, AC010655.2, AC010655.3, METTL2B, Metazoa_SRP, AC090114.2, AC090114.3, AC090114.1, AC108010.1, AC018638.8, RNU6-177P, AC018638.4, AC018638.2, AC018638.1, AC018638.5, CICP14, AC018638.7, AC018638.3, FAM71F2, AC018638.6, IMP3P2, RNA5SP242, RNA5SP243, FAM71F1, CALU, RN7SL81P, OPN1SW, CCDC136, FLNC, FLNC-AS1, KCP, ATP6V1F, ATP6V1FNB, AC025594.1, IRF5, AC025594.2, TNPO3, RN7SL306P, ODCP, TPI1P2, AC018639.1, AC011005.2, AC011005.3, CYCSP20, AC011005.1, TSPAN33, RNY1P11, SMO.
- chr8:150,584–545,781, 17 genes, copy number 6 (within-gene range 4–6): AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3, AC136777.2, AC136777.1, FAM87A, FBXO25, AC083964.1, AC083964.2, TDRP.
- chr8:18,979,619–19,259,469, 5 genes, copy number 7 (within-gene range 2–7): SNORA62, AC009884.1, AC009884.2, AC100849.1, AC100849.2.
- chr8:38,263,130–46,028,892, 131 genes, copy number 5–11 (broad region; genes not listed).
- chr11:37,702,125–46,274,547, 111 genes, copy number 8 (broad region; genes not listed).
- chr11:80,957,317–106,022,403, 413 genes, copy number 5–9 (within-gene range 2–9) (broad region; genes not listed).
- chr12:66,767–3,371,346, 86 genes, copy number 5 (broad region; genes not listed).
- chr12:3,462,718–3,469,296, 2 genes, copy number 5: AC005908.2, AC005908.1.
- chr12:51,951,699–75,984,015, 665 genes, copy number 5–8 (within-gene range 2–8) (broad region; genes not listed).
- chr16:74,671,855–75,556,268, 31 genes, copy number 7 (within-gene range 3–7): MLKL, FA2H, AC009132.1, WDR59, ZNRF1, AC099508.1, LDHD, AC099508.2, ZFP1, AC009078.1, CTRB2, CTRB1, AC009078.2, BCAR1, AC009078.3, RNU6-758P, CFDP1, AC009054.1, AC009054.2, AC009163.2, AC009163.5, AC009163.7, TMEM170A, AC009163.4, CHST6, AC009163.1, AC009163.6, TMEM231P1, AC009163.3, CHST5, TMEM231.
- chr17:55,526,964–66,198,238, 327 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr20:87,250–6,220,759, 196 genes, copy number 6 (broad region; genes not listed).
- chr20:19,208,652–23,190,419, 75 genes, copy number 6 (broad region; genes not listed).
- chr20:30,484,925–37,095,997, 222 genes, copy number 5–8 (within-gene range 3–8) (broad region; genes not listed).
- chr22:15,290,718–21,192,156, 282 genes, copy number 5–19 (broad region; genes not listed).
- chr22:49,372,924–49,964,072, 26 genes, copy number 6: AC207130.1, C22orf34, AL008636.1, AL031593.1, MIR3667, Z97192.1, Z97192.2, Z97192.3, Z97192.4, AL023802.1, RN7SKP252, RPL5P35, BRD1, Z98885.3, Z98885.1, Z98885.2, AL117328.1, Metazoa_SRP, AL117328.2, ZBED4, ALG12, AL671710.1, CRELD2, BX539320.1, PIM3, MIR6821.

Autosomal genes at a single copy (total copy number 1): 357. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
